Somatic mutation profile of tumor specimen 0DIY6D from CCDI case PBBVZG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin of upper limb and shoulder; Age at diagnosis: 1.3 years (493 days).
Specimen 0DIY6D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6983bb77-27bc-4ce2-aa2d-c4eb68374766.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIY5W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28822709-92ef-4383-ae22-e0e72b3170f3

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by muse, mutect2
- AKAP12 | c.1850T>G p.V617G | Missense Mutation (SNP) | VAF 38/609 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 38/1228 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 44/1490 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PABPC5 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 25/830 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 14/259 reads (5%) | called by muse, mutect2
